Somatic mutation profile of tumor specimen TCGA-V4-A9F1-01A (aliquot TCGA-V4-A9F1-01A-11D-A39W-08) from TCGA case TCGA-V4-A9F1, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.1 years (16,852 days).
Specimen TCGA-V4-A9F1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24925fff-7c67-4137-8e54-6b7c7131910c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9F1-10A (Blood Derived Normal), aliquot TCGA-V4-A9F1-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5345c0f7-fcf4-46bb-9013-90dc22510c62

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 33/82 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPI | c.1299C>T p.S433= | Splice Region (SNP) | VAF 19/42 reads (45%) | catalogued as rs773147145; called by muse, mutect2, varscan2
- BAP1 | c.99C>G p.Y33* | Nonsense Mutation (SNP) | VAF 71/96 reads (74%) | catalogued as COSV56234502; called by muse, mutect2, varscan2
- PLD5 | c.1316G>A p.R439H (on ENST00000442594; = p.R377H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs747669178, COSV59139492; called by muse, mutect2, varscan2
- SEMA4A | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV61772484; called by muse, mutect2, varscan2
- TFDP3 | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs767295052, COSV59537261; called by muse, mutect2, varscan2
- C3 | c.4154T>C p.I1385T | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPS8L2 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPL11 | c.135_136dup p.T46Rfs*42 (on ENST00000374550 / NM_001199802.1; = p.T47Rfs*42 on NM_000975.5) | Frame Shift Ins (INS) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
- AADACL4 | c.273C>T p.D91= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs770479268, COSV100879438; called by muse, mutect2, varscan2
- PSG6 | c.1212C>A p.I404= | Silent (SNP) | VAF 69/188 reads (37%) | called by muse, mutect2, varscan2
